Somatic mutation profile of tumor specimen ALCH-B2D6-TTP1-A (aliquot ALCH-B2D6-TTP1-A-1-0-D-A77J-36) from ALCHEMIST case ALCH-B2D6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.6 years (25,063 days).
Specimen ALCH-B2D6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08e6e9f6-cef0-4365-929e-0b54be0f5274.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2D6-NB1-A (Blood Derived Normal), aliquot ALCH-B2D6-NB1-A-1-0-D-A77J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/187ac676-cc73-4f25-b85e-c3666cc86286

The open-access MAF lists 66 somatic variants for this specimen: 49 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 12, Intron 4, Nonsense Mutation 2, 3'UTR 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>A p.A289D | Missense Mutation (SNP) | VAF 34/247 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 82/469 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.9071A>G p.Y3024C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.526); catalogued as COSV67979166; called by muse, mutect2, varscan2
- ALAS2 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM109567; called by muse, mutect2, varscan2
- ARHGAP32 | c.1168C>G p.Q390E (on ENST00000310343 / NM_001378025.1; = p.Q41E on NM_014715.4) | Missense Mutation (SNP) | VAF 14/255 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV59856330; called by muse, mutect2
- ARID1A | c.1543C>T p.Q515* | Nonsense Mutation (SNP) | VAF 28/498 reads (6%) | catalogued as COSV61377807; called by muse, mutect2
- ATE1 | c.703C>G p.Q235E | Missense Mutation (SNP) | VAF 18/468 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.101); catalogued as COSV56436170; called by muse, mutect2
- ATP6V0A4 | c.1684A>G p.N562D | Missense Mutation (SNP) | VAF 27/290 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs961469487; called by muse, mutect2
- AZI2 | c.851G>A p.R284K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs779049060; called by muse, mutect2, varscan2
- CD163L1 | c.2405T>C p.M802T | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1372256623; called by muse, mutect2
- CHMP2B | c.594C>G p.I198M | Missense Mutation (SNP) | VAF 53/287 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.4); catalogued as COSV99773432; called by muse, mutect2, varscan2
- DDX49 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as rs1256473337; called by muse, mutect2
- DNAJA3 | c.1337C>G p.S446C | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV52163177; called by muse, mutect2
- EGFR | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as COSV51770322, COSV99297135; called by muse, mutect2, varscan2
- FAM227A | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1204931038; called by muse, mutect2
- FGF12 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs1239358277, COSV53160176; called by muse, mutect2, varscan2
- FOXP2 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 24/443 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs778748061, COSV100646314, COSV63482676; called by muse, mutect2
- HPF1 | c.274A>G p.K92E | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs772727019; called by muse, mutect2, varscan2
- KALRN | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs1560594705, COSV53780017; called by muse, mutect2
- KIF26B | c.3701G>A p.S1234N | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1372408364, COSV63638455; called by muse, mutect2
- KIF26B | c.3908G>A p.C1303Y | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.656); catalogued as rs1279463099; called by muse, mutect2
- KIF26B | c.4762G>A p.V1588I | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs770177711; called by muse, varscan2
- KIF6 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs757976747, COSV54667341; called by muse, mutect2, varscan2
- KMT2A | c.6593C>G p.S2198C | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV63286205; called by muse, mutect2
- PCDHB14 | c.1975C>T p.H659Y | Missense Mutation (SNP) | VAF 12/322 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV53390014; called by muse, mutect2
- SLC15A4 | c.975C>G p.F325L | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.534); catalogued as COSV99903697; called by muse, mutect2
- ZBTB34 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.229); catalogued as rs1216391479; called by muse, mutect2
- ARHGEF17 | c.6127G>T p.G2043C | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- C4BPA | c.1742T>A p.L581Q | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CC2D1A | c.2076del p.E693Kfs*9 | Frame Shift Del (DEL) | VAF 12/138 reads (9%) | called by mutect2, pindel
- CCDC150 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); called by muse, mutect2
- CFAP92 | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 18/313 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.415); called by muse, mutect2
- DDX49 | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.085); called by muse, mutect2
- IPO5 | c.154A>G p.T52A | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KCNB2 | c.1654C>G p.P552A | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.033); called by muse, mutect2
- KIF26B | c.4372G>C p.E1458Q | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- KLHL11 | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.396); called by muse, mutect2
- NR2E3 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.115); called by muse, mutect2
- PGBD1 | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 22/313 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2
- PKD1 | c.8989A>G p.S2997G | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- POLA2 | c.1171-1G>A p.X391_splice | Splice Site (SNP) | VAF 21/125 reads (17%) | called by muse, mutect2, varscan2
- SLC30A10 | c.17G>A p.G6D | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPSB2 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.071); called by muse, mutect2
- SYT11 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 16/187 reads (9%) | called by muse, mutect2
- TNNI3K | c.2039A>T p.H680L | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- UBR7 | c.518A>C p.E173A | Missense Mutation (SNP) | VAF 30/460 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, mutect2
- WAPL | c.2889C>G p.N963K | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.235); called by muse, mutect2
- ZAN | c.7508A>G p.D2503G | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2
- ZNF34 | c.1405C>T p.H469Y | Missense Mutation (SNP) | VAF 18/508 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2
- A2M | c.2523G>A p.K841= | Silent (SNP) | VAF 22/217 reads (10%) | called by muse, mutect2, varscan2
- COL4A4 | c.2145G>A p.A715= | Silent (SNP) | VAF 40/289 reads (14%) | catalogued as rs773270107, COSV61630100; called by muse, mutect2, varscan2
- CP | c.1902C>G p.L634= | Silent (SNP) | VAF 14/290 reads (5%) | called by muse, mutect2
- GRM8 | c.1656C>T p.S552= | Silent (SNP) | VAF 18/232 reads (8%) | called by muse, mutect2
- KCNA1 | c.702C>T p.F234= | Silent (SNP) | VAF 46/384 reads (12%) | catalogued as rs755621934, COSV66837516; called by muse, mutect2, varscan2
- KIF26B | c.3501G>A p.E1167= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- LTN1 | c.210G>C p.R70= | Silent (SNP) | VAF 10/231 reads (4%) | called by muse, mutect2
- MRPL17 | c.72C>A p.S24= | Silent (SNP) | VAF 21/142 reads (15%) | called by muse, mutect2, varscan2
- PLPPR4 | c.1194C>T p.I398= | Silent (SNP) | VAF 14/210 reads (7%) | called by muse, mutect2
- PRMT8 | c.384C>T p.F128= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as rs187042226; called by muse, mutect2, varscan2
- SCN1A | c.2724C>T p.G908= (on ENST00000303395 / NM_001202435.3; = p.G897= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/412 reads (14%) | called by muse, mutect2, varscan2
- SIL1 | c.1095C>A p.R365= | Silent (SNP) | VAF 18/148 reads (12%) | called by muse, mutect2, varscan2
- ACTR1A | c.*1259G>T | 3'UTR (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- AL138759.1 | n.208-2799A>G | Intron (SNP) | VAF 10/117 reads (9%) | catalogued as rs1413802823; called by muse, mutect2
- LIPF | c.817-49G>A | Intron (SNP) | VAF 13/108 reads (12%) | called by muse, varscan2
- PRKCSH | c.1341-15C>T | Intron (SNP) | VAF 20/216 reads (9%) | catalogued as rs745817056; called by muse, mutect2
- SLC16A7 | c.218-2981G>T | Intron (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2, varscan2
